Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A50L, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A50L-01A (Primary Tumor).

Gross Description: Tumor is located in lower esophagus. It is ulcerated and invasive, making esophagus narrow, with 6x3x0.7cm in size, firm and white-gray surface. Tumor is located in lower esophagus. It is ulcerated and invasive, making esophagus narrow, with 6x3x0.7cm in size, firm and white-gray surface.

Microscopic Description: Squamous cell are hyperplastic and ulcerated. Tumor tissue arranges in the form of group or sheets or trabecular of tumor cells. The malignant cells have moderate, light eosinophilic cytoplasm and form keratinized pearls. The nuclei are enlarged, variability in size and shape, containing coarse clumped chromatin with prominent nucleoli. Mitotic figures are common. Tumor invades fat tissue, in adventitia. Stroma is invasion of inflammatory cells.

Diagnosis Details: Squamous cell carcinoma, Grade II, infiltrating adventitia.

Comments:

Formatted Path Reports: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Esophagectomy

ICD-0-3

Tumor site: Abdominal esophagus

carcinoma, squamous cell, NOS 8070/3

Tumor size: 6 x 3 x 0.7 cm

Path Site: esophagus, abdominal C15.2

Histologic type: Squamous cell carcinoma

CQCF esophagus, distal C15.5

hw
10/29/12

Histologic grade: Moderately differentiated

Tumor extent: Adventitia

Lymph nodes: 1/1 positive for metastasis (Lymph node, group vii 1/1)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Diagnostic Discrepancy		

Source: NCI Genomic Data Commons file 488866d9-3e33-48c3-910c-a171bbdfa369 (TCGA-IG-A50L.FFA1CFEB-B0D1-41B7-8A3A-56F0B7B5EBE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).